Somatic mutation profile of tumor specimen TCGA-RN-A68Q-01A (aliquot TCGA-RN-A68Q-01A-11D-A307-09) from TCGA case TCGA-RN-A68Q, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Spinal meninges; Age at diagnosis: 62.9 years (22,981 days).
Specimen TCGA-RN-A68Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5702cdb-51d8-4af7-9ede-17fba981c6f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RN-A68Q-10A (Blood Derived Normal), aliquot TCGA-RN-A68Q-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5d851f0-a426-4065-939e-80ac51f53d82

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.605C>G p.A202G | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV99190878; called by muse, mutect2, varscan2
- ABCG4 | c.1869G>T p.L623F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100266481; called by muse, mutect2
- CORO7-PAM16 | c.3038G>C p.G1013A | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99267288; called by muse, mutect2
- HAUS3 | c.710A>G p.N237S | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.131); catalogued as rs368361238, COSV99704126; called by muse, mutect2, varscan2
- IL1A | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as COSV99641233; called by muse, mutect2, varscan2
- LARP1 | c.3029A>T p.K1010I (on ENST00000518297 / NM_033551.3; = p.K933I on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV100303374; called by muse, mutect2, varscan2
- ZFR2 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as COSV99506941; called by muse, mutect2, varscan2
- GAS2L2 | c.1880C>A p.S627Y | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2
- SOX10 | c.514_519dup p.K172_Y173dup | In Frame Ins (INS) | VAF 25/80 reads (31%) | called by mutect2, varscan2
- GPT | c.405C>T p.D135= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs775371734, COSV52954412, COSV99477349; called by muse, mutect2, varscan2
- KRTAP12-1 | c.111C>T p.P37= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as rs782192568, COSV59964585; called by muse, mutect2, varscan2
- VWF | c.2607G>A p.T869= | Silent (SNP) | VAF 44/210 reads (21%) | catalogued as rs762512650, COSV54627260, COSV54628936, COSV99777823; called by muse, mutect2, varscan2
- PLPPR3 | c.658-33G>C | Intron (SNP) | VAF 25/159 reads (16%) | catalogued as COSV62459532; called by muse, mutect2, varscan2
